Gene-level copy-number profile of tumor specimen ALCH-B29X-TTP1-A from ALCHEMIST case ALCH-B29X, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.1 years (27,076 days).
Specimen ALCH-B29X-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file de4796fc-c5f7-4f46-8824-44a2a0ba7a10.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B29X-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/35cd692e-43f1-4992-8246-680ba48f29ad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 121; copy number 1: 7,444; copy number 2: 49,910; copy number 3: 903; copy number 4: 17; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 121 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–71,585, 3 genes: OR4G4P, OR4G11P, OR4F5.
- chr2:232,368,576–232,368,697, 1 gene: AC068134.3.
- chr2:232,479,827–232,487,834, 1 gene: ECEL1.
- chr4:68,509,441–68,517,647, 1 gene: UGT2B29P.
- chr7:76,361,768–76,442,071, 3 genes: PPIAP81, SSC4D, ZP3.
- chr9:65,189,995–66,179,474, 27 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:54,591,480–54,725,816, 11 genes: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P.
- chr12:12,891,559–12,917,937, 2 genes: GPRC5A, MIR614.
- chr12:12,940,775–12,952,147, 1 gene (within-gene range 0–2): GPRC5D.
- chr12:53,962,308–53,977,643, 6 genes: HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11.
- chr12:131,828,393–131,864,538, 2 genes: MMP17, AC131009.2.
- chr15:25,169,337–25,250,940, 45 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr16:58,665,109–58,684,770, 1 gene: SLC38A7.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–1): PKD1L2, RNU6-1191P, AC092718.9.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.
- chr18:29,048,620–29,048,719, 1 gene: RNU6-408P.
- chr19:17,871,945–17,943,991, 2 genes: SLC5A5, CCDC124.
- chr22:43,038,585–43,089,419, 2 genes: TTLL1-AS1, TTLL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,246,755–43,254,089, 4 genes, copy number 5: AC022616.5, AC022616.7, AC022616.3, AC022616.2.

Autosomal genes at a single copy (total copy number 1): 6,851. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
